CPTAC case C3L-06212 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb39e099-c2b7-45d8-9053-88486b16f87f

Demographics
Sex at birth: male; Race: white; Year of birth: 1943; Vital status: Dead; Days to death: 2,638 days (7.2 years); Year of death: 2022; Cause of death: Cancer Related; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 72.2 years (26,356 days); Year of diagnosis: 2015; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 2,638 days (7.2 years); Progression or recurrence: yes; Days to recurrence: 2,487 days (6.8 years); Days to last follow up: 2,638 days (7.2 years); Clark level: III; Tumor focality: Unifocal; Ulceration indicator: No.
   Pathology details: Breslow thickness category: <=1 mm; Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 6; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 2,316 days (6.3 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 2,638 days (7.2 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1,924 days (5.3 years); Initial weight: 118 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide CPT042501 0001: Section location: Lymph node; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-06212-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1,921 days (5.3 years); Method of sample procurement: Blood Draw.
